Somatic mutation profile of tumor specimen TARGET-10-PATCNI-09A (aliquot TARGET-10-PATCNI-09A-01D) from TARGET case TARGET-10-PATCNI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,682 days).
Specimen TARGET-10-PATCNI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e407d7b3-030c-45a4-8799-8fa6d1bbf2da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATCNI-10A (Blood Derived Normal), aliquot TARGET-10-PATCNI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ca0e371-6a4e-45e5-81fc-035267da9c4b

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADL | c.427T>C p.S143P | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52054234; called by muse, mutect2, varscan2
- ACTL8 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64861925; called by muse, mutect2, varscan2
- CMC4 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs781882014, COSV62899912; called by muse, mutect2, varscan2
- CRYBG2 | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs745656556, COSV57487355; called by muse, mutect2, varscan2
- FAM120C | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.755); catalogued as COSV60260396; called by muse, mutect2, varscan2
- LAMA2 | c.7132A>T p.M2378L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.669); catalogued as rs769562504, COSV70344793, COSV70351177; called by muse, mutect2, varscan2
- NOTCH1 | c.4847T>A p.I1616N | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53028112; called by muse, mutect2, varscan2
- PNPLA3 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs370175838; called by muse, mutect2, varscan2
- CTAGE1 | c.*946G>T | 3'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- RNU6-714P | chr9:92818419 C>A | 5'Flank (SNP) | VAF 49/143 reads (34%) | called by muse, mutect2, varscan2
